Somatic mutation profile of tumor specimen TCGA-A6-5657-01A (aliquot TCGA-A6-5657-01A-01D-1650-10) from TCGA case TCGA-A6-5657, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.5 years (23,920 days).
Specimen TCGA-A6-5657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea5e120-0e8f-46a2-b45a-fc1839bbd66a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5657-10A (Blood Derived Normal), aliquot TCGA-A6-5657-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bce4391-74f0-4384-bd75-7639c8eac797

The open-access MAF lists 131 somatic variants for this specimen: 92 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 36, Nonsense Mutation 6, Frame Shift Ins 4, Frame Shift Del 2, Intron 2, Splice Region 1, Splice Site 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 31/182 reads (17%) | catalogued as rs1254176854, CM106359, COSV57331724, COSV57359899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 54/284 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 103/682 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTL6B | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99355809; called by muse, mutect2, varscan2
- ADD2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs200519011, COSV52457097; called by muse, mutect2, varscan2
- ADGRL2 | c.2101G>T p.A701S (on ENST00000370717 / NM_001366005.1; = p.A688S on NM_012302.4) | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV54653894, COSV54693439; called by muse, mutect2, varscan2
- ATP1A3 | c.2572G>A p.G858R (on ENST00000545399 / NM_001256214.2; = p.G845R on NM_152296.5) | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.971); catalogued as COSV57491195; called by muse, mutect2
- BAX | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53172090; called by muse, mutect2, varscan2
- BNC2 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV66149947; called by muse, mutect2, varscan2
- C11orf1 | c.10T>G p.S4A | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99500463; called by muse, mutect2
- CACNA1E | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs769232172, COSV100702048, COSV62382687; called by mutect2, varscan2
- CACNA1I | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400949374, COSV60820119; called by muse, varscan2
- CBFA2T3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs370027238; called by muse, mutect2, varscan2
- CCDC158 | c.509C>A p.T170K | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV101187428; called by muse, mutect2, varscan2
- CDC25C | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs766572046, COSV60400140; called by muse, mutect2, varscan2
- CPZ | c.323G>A p.R108Q (on ENST00000360986 / NM_001014447.3; = p.R97Q on NM_003652.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as rs776676610, COSV59926682; called by muse, mutect2, varscan2
- CTNNA1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 65/474 reads (14%) | catalogued as rs201498915, COSV57069365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAAM2 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as rs762109044, COSV51421705; called by muse, mutect2, varscan2
- DNAH5 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs532394572, COSV54247933; called by muse, mutect2, varscan2
- DNAH9 | c.2932G>T p.D978Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV52332421, COSV99308810; called by muse, mutect2, varscan2
- DSCAM | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs755700184, COSV101261758; ClinVar: likely benign; called by mutect2, varscan2
- DSPP | c.3596G>A p.S1199N | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV99218187; called by muse, mutect2, varscan2
- EMCN | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 78/536 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV56465281; called by muse, mutect2, varscan2
- ENAM | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as rs779308123, COSV68537283; called by muse, mutect2, varscan2
- EPHB6 | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV67421253; called by muse, mutect2, varscan2
- FAM169A | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 110/624 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV65847072; called by muse, mutect2, varscan2
- FAM170A | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV58926218; called by muse, mutect2
- FAM189B | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs1397346491, COSV59171348; called by muse, mutect2, varscan2
- FASTK | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs774195132, COSV52542672; called by muse, mutect2, varscan2
- FCGBP | c.6802G>A p.V2268M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.623); catalogued as rs953788782; called by muse, mutect2
- FCGBP | c.6599C>T p.P2200L | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370331745; called by muse, mutect2
- FSTL5 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100062342; called by muse, varscan2
- GABRB3 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs769693685, COSV54677415, COSV54682323; called by mutect2, varscan2
- GALK2 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.333); catalogued as COSV59105993; called by muse, mutect2, varscan2
- GALNTL5 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1434435791, COSV67181460; called by muse, mutect2, varscan2
- GFM2 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780917501, COSV57193831; called by muse, mutect2, varscan2
- GJA10 | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.688); catalogued as COSV101005464; called by muse, mutect2, varscan2
- GNRHR | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280668, COSV56933293; called by muse, mutect2, varscan2
- GPR149 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV67670761; called by muse, mutect2, varscan2
- HGF | c.1172G>T p.C391F | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV55958392; called by muse, mutect2, varscan2
- HIP1 | c.1326G>T p.R442S | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100418260; called by muse, mutect2, varscan2
- HYDIN | c.9967G>T p.A3323S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.146); catalogued as COSV66890657; called by muse, mutect2, varscan2
- IBSP | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as rs1340518412, COSV99883857; called by muse, mutect2, varscan2
- IRS4 | c.3604C>A p.Q1202K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV64536444; called by muse, mutect2, varscan2
- ITGAL | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100776390; called by muse, mutect2, varscan2
- ITM2A | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 108/230 reads (47%) | catalogued as COSV64811710; called by muse, mutect2, varscan2
- KCNMB1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as rs369035536; called by muse, mutect2, varscan2
- KCTD1 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58691757; called by muse, mutect2, varscan2
- LPAR1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs769855870, COSV62690346; called by muse, mutect2
- LTN1 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1253307641, COSV63735549; called by muse, mutect2, varscan2
- LXN | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV51836329; called by muse, mutect2, varscan2
- MROH2B | c.4136G>A p.R1379Q | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs753433063, COSV68182217; called by muse, mutect2, varscan2
- MUC5B | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs758528992, COSV101500097, COSV71596525; called by muse, mutect2, varscan2
- MYADM | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472582740; called by muse, mutect2, varscan2
- NFATC4 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as rs1352210330, COSV51599932; called by muse, mutect2, varscan2
- NRG1 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55178633; called by muse, mutect2, varscan2
- NUSAP1 | c.779G>C p.S260T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV52973983; called by muse, mutect2, varscan2
- OBSCN | c.13070C>T p.A4357V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775800297, COSV52815831; called by mutect2, varscan2
- OBSL1 | c.3710C>A p.P1237Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.697); catalogued as COSV54711114; called by muse, mutect2, varscan2
- OSBPL3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376708281; called by muse, varscan2
- OTOGL | c.1109C>T p.S370F (on ENST00000547103; = p.S361F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV72007743; called by muse, mutect2, varscan2
- PCDH11X | c.2728G>T p.D910Y | Missense Mutation (SNP) | VAF 195/454 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53484616; called by muse, mutect2, varscan2
- PCDH15 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57317010; called by muse, mutect2, varscan2
- PCDHA2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV65371830; called by muse, mutect2, varscan2
- PCF11 | c.1760A>C p.N587T | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53531570, COSV53538628; called by muse, mutect2, varscan2
- PHF13 | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV99276039; called by muse, mutect2, varscan2
- PKD1L1 | c.7351G>T p.E2451* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV51845520; called by muse, mutect2, varscan2
- PRDM4 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV57308013; called by muse, mutect2, varscan2
- PTN | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV100781060, COSV61965817; called by muse, mutect2, varscan2
- RALYL | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV72826649; called by muse, mutect2, varscan2
- RBMXL2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60981627; called by muse, mutect2, varscan2
- RPA4 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV61295989; called by muse, mutect2, varscan2
- RPL5 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs200315052, COSV59873342; called by muse, mutect2, varscan2
- SLFN11 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs546044791, COSV57698837; called by muse, mutect2, varscan2
- SLITRK1 | c.134dup p.F47Lfs*30 | Frame Shift Ins (INS) | VAF 18/144 reads (13%) | catalogued as rs763682501; called by mutect2, varscan2
- SPANXC | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV62842114, COSV62842334; called by muse, mutect2
- STK11 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs762482152, CM087675, COSV99289997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNM | c.4478C>T p.A1493V (on ENST00000336292 / NM_145728.3; = p.A1181V on NM_015286.6) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs372660853; called by muse, mutect2
- TIAM1 | c.4690G>T p.G1564* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | catalogued as COSV54578857; called by muse, mutect2, varscan2
- TRABD | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs374922285; called by muse, mutect2, varscan2
- TRAIP | c.156+1G>A p.X52_splice | Splice Site (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100513483; called by mutect2, varscan2
- TTI2 | c.1080G>T p.R360S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100659854; called by muse, mutect2, varscan2
- TTN | c.42974G>C p.S14325T (on ENST00000591111; = p.S6901T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | PolyPhen probably damaging (0.991); catalogued as COSV60402815; called by muse, mutect2, varscan2
- UBE2Q1 | c.873C>T p.L291= | Splice Region (SNP) | VAF 19/145 reads (13%) | catalogued as COSV52727341; called by muse, mutect2, varscan2
- VPS13B | c.5492A>G p.N1831S | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.32); catalogued as COSV62160323; called by muse, mutect2, varscan2
- ZNF135 | c.685C>A p.L229I (on ENST00000313434 / NM_001289401.2; = p.L241I on NM_003436.4) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100536994; called by muse, mutect2, varscan2
- ZNF644 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 85/594 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61350841; called by muse, mutect2, varscan2
- ANKRD2 | c.641_644del p.D214Afs*13 | Frame Shift Del (DEL) | VAF 20/212 reads (9%) | called by mutect2, pindel
- APC | c.4483_4486dup p.T1496Kfs*19 | Frame Shift Ins (INS) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- CSNK1G3 | c.478_479dup p.R161Tfs*4 | Frame Shift Ins (INS) | VAF 87/674 reads (13%) | called by mutect2, pindel, varscan2
- EPB41 | c.2412del p.K805Rfs*3 (on ENST00000343067 / NM_001166005.2; = p.K596Rfs*3 on NM_203342.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- PLCXD3 | c.18dup p.K7Efs*32 | Frame Shift Ins (INS) | VAF 24/175 reads (14%) | called by mutect2, pindel, varscan2
- ACADS | c.294C>T p.Y98= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs143169456; called by muse, mutect2, varscan2
- ADAMTS2 | c.282C>T p.T94= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV51114633; called by muse, mutect2, varscan2
- AKNA | c.2685C>T p.I895= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV56315372, COSV99800478; called by muse, mutect2, varscan2
- BMP7 | c.882G>A p.T294= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1391413155, COSV67782186; called by muse, mutect2, varscan2
- CCDC136 | c.1929C>T p.H643= | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as rs781253420, COSV52803672; called by muse, mutect2, varscan2
- CD52 | c.81C>T p.N27= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs770977151, COSV57490856; called by muse, mutect2, varscan2
- CDH4 | c.954C>T p.I318= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs999341553, COSV64654231; called by muse, mutect2, varscan2
- CDH5 | c.1266A>C p.T422= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs752714451, COSV58520449; called by muse, mutect2, varscan2
- CRIP3 | c.120C>T p.S40= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV51482795; called by muse, mutect2, varscan2
- DPP10 | c.720C>T p.I240= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as rs753852164, COSV59660437, COSV59681570; called by muse, mutect2, varscan2
- DPY19L2 | c.1945C>T p.L649= | Silent (SNP) | VAF 62/452 reads (14%) | catalogued as rs538001119, COSV100193805, COSV100194175; called by muse, mutect2, varscan2
- DSCAM | c.2364G>A p.A788= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as rs41445950; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM78B | c.339T>A p.P113= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV57975087; called by muse, mutect2
- G6PC3 | c.480G>A p.S160= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs145419406; called by muse, mutect2, varscan2
- H4C9 | c.123C>T p.R41= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs1260821773, COSV62890337; called by muse, mutect2, varscan2
- KPTN | c.1113C>T p.H371= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs373396737, COSV52643505; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT83 | c.261G>A p.S87= | Silent (SNP) | VAF 41/358 reads (11%) | catalogued as rs1359689232, COSV99532003; called by muse, varscan2
- LPXN | c.204G>A p.E68= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as rs767817463, COSV101223174; called by muse, mutect2, varscan2
- LTO1 | c.413G>A p.*138= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV54163764, COSV99654117; called by muse, mutect2, varscan2
- MAGEA1 | c.867A>G p.R289= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as COSV100756697; called by muse, mutect2
- MARCHF10 | c.1188G>A p.A396= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs751298866, COSV60889648; called by muse, mutect2, varscan2
- MMP11 | c.1068C>T p.F356= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV53158323; called by muse, mutect2, varscan2
- NEB | c.1848C>T p.D616= | Silent (SNP) | VAF 93/694 reads (13%) | catalogued as rs530242068, COSV51424340; called by muse, mutect2, varscan2
- NR1H4 | c.1065G>A p.P355= (on ENST00000551379 / NM_001206993.2; = p.P341= on NM_005123.4) | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs569479207, COSV51857715; called by muse, mutect2, varscan2
- NRM | c.183C>G p.A61= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV99223994; called by muse, mutect2
- QRICH2 | c.4503G>A p.K1501= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV53158610; called by muse, mutect2, varscan2
- RNF180 | c.1095G>A p.L365= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as COSV56961774; called by muse, mutect2, varscan2
- SETX | c.1683G>A p.K561= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV56396645; called by muse, mutect2, varscan2
- SH2D7 | c.534C>T p.P178= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs1272515752, COSV60928108; called by muse, mutect2, varscan2
- TACC2 | c.2529C>T p.D843= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs368173512; called by muse, mutect2, varscan2
- TET1 | c.5715C>T p.G1905= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs372654275; called by muse, mutect2, varscan2
- TMEM120B | c.885C>T p.H295= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs368743483; called by muse, mutect2, varscan2
- TRAF7 | c.1599G>T p.L533= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58218906; called by muse, mutect2, varscan2
- USP24 | c.3762G>A p.T1254= | Silent (SNP) | VAF 73/430 reads (17%) | catalogued as rs573136414, COSV53780550; called by muse, mutect2, varscan2
- ZNF404 | c.75G>A p.S25= | Silent (SNP) | VAF 23/234 reads (10%) | catalogued as rs368554205, COSV60989236; called by muse, mutect2, varscan2
- ZNF512 | c.921G>A p.R307= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs972201543, COSV100821127; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172436 C>A | 5'Flank (SNP) | VAF 39/238 reads (16%) | catalogued as COSV101346378; called by muse, mutect2, varscan2
- SLIT2 | c.1463-578C>T | Intron (SNP) | VAF 29/181 reads (16%) | catalogued as rs1261393936, COSV56588435; called by muse, mutect2, varscan2
- TTN | c.10303+2189C>A | Intron (SNP) | VAF 26/185 reads (14%) | catalogued as COSV59948466, COSV60013315, COSV60402847; called by muse, mutect2, varscan2
